Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8ER, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8ER-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell NOS
Date: Esophagus, distal third
Esophagus NOS
11/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus

PATHOLOGY REPORT:

1.
Specimen: thoracic and abdominal esophagus and proximal stomach
Procedure: Esophagogastrectomy
Tumor site: distal esophagus and stomach
Tumor size (greatest dimension): 7,8 cm
Histologic type: Squamous cell carcinoma, ulcerated
Histologic grade: G2 moderately differentiated
Microscopic tumor extension: tumor invades mucosa, submucosa, muscularis propria and adventitia
Lymph-vascular invasion: not identified
Perineural invasion: not identified
Margins:
Proximal margin: uninvolved by carcinoma
Distal margin: uninvolved by carcinoma
Circumferential (radial margin): involved by invasive carcinoma
Regional lymph nodes from lesser curvature with conglomerate:
Number examined: 08
Number positive for neoplasia: 03
2. "Lymph nodes of the hepatic artery":
Number examined: 06
Number positive for neoplasia: 00
3. "Margin of the stomach":
Uninvolved by carcinoma

ICD-0 Discrepancy		✓
For Pathology History		✓
Site Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file f5cee32c-a438-4de9-8579-f6c863bd3935 (TCGA-VR-A8ER.E984A958-58F7-42DD-9B75-51147814701B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).